HCMI case HCM-STAN-0914-C34 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b9ff4f43-7add-4cf0-a72d-cdfc92cc6b7d

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Year of birth: 1962; Vital status: Dead; Days to death: 1,280 days (3.5 years).

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.9; Tissue or organ of origin: Lung, NOS; Classification of tumor: primary; Age at diagnosis: 53.4 years (19,510 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IVA; AJCC pathologic T: T1a; AJCC pathologic N: N3; AJCC pathologic M: M1a; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: No; Sites of involvement: Pleura.
   Recorded as not given: neoadjuvant treatment (type not reported); Surgery, NOS, for initial diagnosis.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C34.9; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Laterality: Right; Classification of tumor: recurrence; Age at diagnosis: 55.9 years (20,400 days); Days to diagnosis: 890 days (2.4 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Osimertinib; Treatment intent type: Maintenance Therapy; Days to treatment start: 704 days (1.9 years); Treatment outcome: Progressive Disease.

Follow-up (2 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 0 days.
- Days to follow up: 1,280 days (3.5 years); Disease response: Progressive Disease; Progression or recurrence: Yes.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.
- EGFR deletion: Positive; Exon: 19.
- EML4–ALK translocation (FISH): Negative; Second exon: 20.
- EML4–ALK translocation (Sequencing, NOS): Negative; Second exon: 20.
- KRAS mutation, nos: Negative.
- MET: Negative.
- RET rearrangement: Negative.
- ROS1 rearrangement (FISH): Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 60 kg; Height: 180 cm; BMI: 18.5.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (1 sample)
- Sample HCM-STAN-0914-C34-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
